MMRF case MMRF_2388 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/03e0bf5a-b0ae-41dc-94a9-9abab769f1d4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,064 days); ISS stage: II; Days to last known disease status: 822 days (2.3 years); Days to last follow up: 822 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 633 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 822.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 3.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 226 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 44.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.68 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 10.5 g/dL; Glucose 3.08 mmol/L.
- Day 85 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 47 g/L; Total Protein 7.7 g/dL; Glucose 4.24 mmol/L.
- Day 178 (ECOG 1): M Protein 0.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 3.25 mmol/L.
- Day 255 (ECOG 1): M Protein 0.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 7.74 ×10⁹/L; Platelets 327 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 6.44 mmol/L.
- Day 367 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 451 (ECOG 1): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 3.52 mmol/L.
- Day 563 (ECOG 1): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 3.63 mmol/L.
- Day 619 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 47.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 3.85 mmol/L.
- Day 731 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 3.91 mmol/L.
- Day 801 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 9.07 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 3.74 mmol/L.

Other clinical attributes
- Day 1: Weight: 63 kg; Height: 169 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2388_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2388_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
